Somatic mutation profile of tumor specimen TARGET-10-PAPDFS-09A (aliquot TARGET-10-PAPDFS-09A-01D) from TARGET case TARGET-10-PAPDFS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,503 days).
Specimen TARGET-10-PAPDFS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1096c097-bd0d-49ea-bb7e-6a7c79291772.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDFS-10A (Blood Derived Normal), aliquot TARGET-10-PAPDFS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb6cb9f-e14c-4eff-8ea5-c70d55121cdc

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2524T>C p.Y842H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519762, COSV54057460; ClinVar: likely pathogenic; called by muse, varscan2
- CDH10 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.392); catalogued as rs779851472, COSV52589267; called by muse, mutect2, varscan2
- DLK1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs773403233, COSV57990936; called by muse, mutect2, varscan2
- ESX1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV65424685; called by muse, mutect2, varscan2
- KCNMA1 | c.2714C>T p.T905M (on ENST00000286628 / NM_001161352.2; = p.T847M on NM_002247.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201192736, COSV54251924, COSV54268594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCE1 | c.5881C>T p.R1961* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs774196868, COSV53371264; called by muse, mutect2, varscan2
- RNF112 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs371802885; called by muse, mutect2, varscan2
- SPTBN2 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); catalogued as rs771282751; called by muse, mutect2, varscan2
- GOLGA6L2 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GRIPAP1 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTHFD1 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RALYL | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- RASGRP3 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTP4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN1A | c.3430-7C>T | Splice Region (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- USP24 | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DHRS7C | c.249C>T p.S83= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs765257727; called by muse, mutect2, varscan2
- H3C8 | c.33C>T p.S11= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs900352556; called by muse, mutect2, varscan2
- IFT74 | c.447A>G p.Q149= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs1383982407; called by muse, mutect2, varscan2
- TBX22 | c.36G>A p.V12= | Silent (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
